Surgical pathology report (de-identified scan), TCGA case TCGA-D7-A74B, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D7-A74B-01A (Primary Tumor).

Patient: XXX

Age:

Gender: F

Examination result No.

Unit in charge:

Physician in charge:

Clinical diagnosis (suspicion) **Suspected gastric cancer**

Date of admission:

ICD-O-3
Adenocarcinoma, diffuse type
8145/3
Site ^{CSCF} Fundus of stomach C16.1
path
Stomach NOS C16.9
9/10/26/13

Material:

1) Material: stomach. Method of collection: Total organ resection

Histopathological Diagnosis:

Examination performed on:

Poorly differentiated stomach adenocarcinoma. Metastases to 13/22 adjacent lymph nodes. G3, pT3, pN3, R1 (8140/3 T-63000)*

* codes according to ICD-O-3 or SNOMED

Macroscopic description:

Stomach, after being incised along the greater curvature sized 17.3 x 13.2cm with the omentum sized 17 x 8cm. Thickening in the stomach wall over the area of 11.8 x 12.3 x 1.3cm. The lesion is located 0.8cm away from the proximal excision line, and 3.6cm from the distal one.

Microscopic description:

Poorly differentiated gastric adenocarcinoma (G3 acc. to Lauren, diffuse type).

The tumour infiltrates the subserosa and fat tissue of the lesser curvature. The distal excision line shows cancer infiltration. Proximal line free of cancerous lesions. Metastases to 0/1 pericardial lymph node, 3/7 lesser curvature lymph nodes, 5/5 greater curvature lymph nodes, 3/3 peripyloric lymph nodes - total: 11/16 lymph nodes involved. Persisting (+++), active (++) inflammation outside the tumour.

Assistant

Pathologist:

Edited by

CONTACT YOUR DOCTOR WITH THIS REPORT!

Diagnosis Discrepancy	lw 9/17/13	✓

Source: NCI Genomic Data Commons file 6f00f1d2-fba7-4665-aae2-7eef6392a9dd (TCGA-D7-A74B.DCF03F04-DD9B-40EB-BFB3-0BFFBD028E3D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).